Surgical pathology report (de-identified scan), TCGA case TCGA-BP-4782, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MSKCC, specimen TCGA-BP-4782-01A (Primary Tumor).

[page 1 of 4]
Accession #:

Date of Procedure:

Date of Receipt:

Date of Report:

Account #:

Billing Type:

Additional Copy to:

Clinical Diagnosis & History:

with history of left renal mass.

Specimens Submitted:

- 1: SP: Kidney, Left, tumor with cyst wall, partial nephrectomy
- 2: SP: Kidney, Left, anterior cyst, resection
- 3: SP: Kidney, Left, lower pole, cyst, resection
- 4: SP: Kidney, large anterior wall cyst, resection
- 5: SP: Kidney, Residual cyst wall, resection

DIAGNOSIS:

1. SP: Kidney, Left, tumor with cyst wall, partial nephrectomy

Tumor Type:

Renal cell carcinoma - Conventional (clear cell) type

Multiple clear cell-lined cysts, some resembling tiny multilocular cystic renal cell carcinoma are also present.

Fuhrman Nuclear Grade:

Nuclear grade II/IV

Tumor Size:

Greatest diameter is 4.2 cm.

Local Invasion (for renal cortical types):

Not Identified

Renal Vein Invasion:

N/A

Surgical Margins:

Free of tumor

Non-Neoplastic Kidney:

Mild arteriosclerotic changes

Adrenal Gland:

Not identified

Lymph Nodes:

Not identified

Staging for renal cell carcinoma/oncocytoma:

pT1 Tumor <= 7.0 cm in greatest dimension limited to the kidney

2. SP: Kidney, Left, anterior cyst, resection

[page 2 of 4]
Benign fat and fibrous tissue, consistent with benign cortical cyst

3. SP: Kidney, Left, lower pole, cyst, resection
Clear cell lined unilocular cyst
Muscle predominant angiolipoma (0.6 cm), adjacent to the cyst.
(Immunostains for HMB-45, A103, and SMA were performed and results confirm the diagnosis).

4. SP: Kidney, large anterior wall cyst, resection
Clear cell lined unilocular cyst.

5. SP: Kidney, Residual cyst wall, resection

Benign cortical cyst
No lining is identified.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

Special Studies:

Result	Special Stain	Comment
	HMB-45	
	A103	
	SMA	
	NEG CONT	
	IMM RECUT	

Gross Description:

1) The specimen is received fresh, labeled "Left renal tumor with cyst wall" and consists of a 5.0 by 4.5 x 3.5 cm piece of renal parenchyma, the deep surface of which is denoted by a suture. The capsular surface is inked black and the parenchymatous margin including the deep margin is inked blue. Sectioning reveals a well-circumscribed 4.2 x 2.5 x 2 cm tumor with bright yellow, hemorrhagic and gray hyalinized areas. The tumor lies adjacent to a 1.2 cm unilocular renal cortical cyst. The tumor abuts the capsule and is 0.5 cm from the deep margin. The adjacent renal parenchyma appears grossly unremarkable. Also present in the container are multiple pieces of perinephric fat, measuring 9.0 by 7.0 by 2.0 cm in aggregate. Tissue is submitted for TPS. Representative sections are submitted.

Summary of sections:
FSC-frozen section control
T-tumor
CYST-cyst wall
RP-renal parenchyma
PNF-perinephric fat

2) The specimen is received in formalin, labeled "Left anterior kidney cyst" and consists of an irregular fragment of fatty and tan soft tissue which measures 1 x 1.3 x 0.3 cm. Entirely submitted.

Summary of sections:
CYST-entire tissue

3) The specimen is received in formalin, labeled "Left lower pole kidney cyst" and consists of two irregular fragments of dark brown soft tissue which measure in aggregate, 0.8 x 0.5 x 0.2 cm. Entirely submitted.

[page 3 of 4]
Summary of sections:
CYST-entire tissue

4) The specimen is received in formalin, labeled "Large anterior wall kidney cyst" and consists of a flat piece of membranous cyst wall which measures 2.4 x 1 x 0.1 cm with attached adipose tissue which measures 1.9 x 1.1 x 0.2 cm. Entirely submitted.

Summary of sections:
CYST-cyst wall

5) The specimen is received in formalin, labeled "Residual cyst wall" and consists of a piece of renal parenchyma, measuring 3.5 x 1.7 x 1.1 cm. The renal parenchymal resection margin is inked black. An opened unilocular cyst is located under the capsule, measuring 2 x 1 x 0.5 cm. Representative sections are submitted.

Summary of sections:
CYST-cyst wall

Summary of Sections:

Part 1: SP: Kidney, Left, tumor with cyst wall, partial nephrectomy

Block	Sect. Site	PCs
1	cyst	2
1	fsc	1
2	pnf	2
1	rp	1
6	t	6

Part 2: SP: Kidney, Left, anterior cyst, resection

Block	Sect. Site	PCs
1	cyst	1

Part 3: SP: Kidney, Left, lower pole, cyst, resection

Block	Sect. Site	PCs
1	cyst	1

Part 4: SP: Kidney, large anterior wall cyst, resection

Block	Sect. Site	PCs
2	cyst	2

Part 5: SP: Kidney, Residual cyst wall, resection

Block	Sect. Site	PCs
4	cyst	4

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

- 1) FROZEN SECTION DIAGNOSIS: BENIGN ADIPOSE TISSUE.
PERMANENT DIAGNOSIS: SAME

Source: NCI Genomic Data Commons file 056d74de-3db1-4c58-84be-73049a774f69 (TCGA-BP-4782.A26A3E34-6CBB-4DDD-8452-3ECBA5AAF715.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).